Gene-level copy-number profile of tumor specimen TCGA-HD-8224-01A from TCGA case TCGA-HD-8224, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Base of tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 63.2 years (23,069 days).
Specimen TCGA-HD-8224-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.dbe72845-f81e-46b1-8b4d-f664ea24d5ff.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HD-8224-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/113fd2d4-0b8f-4530-8d62-e05c6cd4cd93

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 62; copy number 1: 13,536; copy number 2: 19,802; copy number 3: 14,176; copy number 4: 8,135; copy number 5: 3,176; copy number 6: 574; copy number 7: 278; copy number 8: 72.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HD-8224-01A-11D-2390-01): tumor purity 0.64, ploidy 2.1, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 62 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:8,059,572–8,199,973, 1 gene (within-gene range 0–1): AC105233.4.
- chr8:8,116,745–8,424,648, 8 genes: SNRPCP17, ENPP7P1, FAM85B, AC068020.1, FAM86B3P, ALG1L13P, PRAG1, AC103957.1.
- chr8:12,719,132–16,915,044, 45 genes: MIR5692A2, LONRF1, MIR3926-1, MIR3926-2, AC123777.1, LINC00681, TRMT9B, AC135352.1, RNU6-842P, DLC1, AC106845.1, Y_RNA, AC019270.1, MTND4P7, RNA5SP255, C8orf48, AC022832.1, AC022832.2, AC022880.2, AC022880.1, AC022690.2, AC022690.1, AC023538.1, SGCZ, AC022039.1, EIF4EP5, RNU7-153P, Y_RNA, RNU6-397P, AC040926.1, MIR383, AC084838.1, AC103851.1, TUSC3, AC100850.1, PPM1AP1, AC018437.3, AC018437.1, AC018437.2, MSR1, CCT3P1, MRPL49P2, AC011586.2, AC011586.1, RN7SL474P.
- chr14:21,797,287–21,869,365, 8 genes: TRAV8-1, TRAV9-1, TRAV10, TRAV11, TRAV12-1, TRAV8-2, TRAV8-3, TRAV13-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,100 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:158,831,351–189,814,918, 662 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr2:207,217,532–211,299,189, 67 genes, copy number 5 (broad region; genes not listed).
- chr2:211,535,653–211,535,769, 1 gene, copy number 5: RNA5SP119.
- chr3:77,811,741–78,161,992, 5 genes, copy number 6: RNU6-217P, LINC02077, AC117462.1, RN7SL647P, RN7SKP61.
- chr3:165,772,904–198,222,513, 629 genes, copy number 5–7 (broad region; genes not listed).
- chr5:58,198–14,532,128, 256 genes, copy number 5 (broad region; genes not listed).
- chr6:82,892,390–87,070,461, 60 genes, copy number 5: UBE3D, LAP3P1, AL355613.1, DOP1A, PGM3, RWDD2A, ME1, AL391416.1, PRSS35, SNAP91, AL136972.1, AL139232.1, RIPPLY2, CYB5R4, AL034347.1, LINC02857, MRAP2, CEP162, LINC01611, SMARCE1P2, TBX18, TBX18-AS1, AL590143.1, AL035694.1, AL109941.1, AL139806.1, AL122016.1, AL135903.1, KRT18P64, LINC02535, DUTP5, TPT1P6, NT5E, AL589666.2, SNX14, AL589666.1, SYNCRIP, SNHG5, PKMP3, SNORD50B, AL355615.1, SMIM11P1, RNU4-72P, Y_RNA, AL450338.1, AL450338.2, RNU4-12P, RPL7P27, RAB1AP2, NDUFA5P9, AL391417.1, RN7SL643P, AL353133.1, AL353133.2, AL157777.1, AL157777.2, HTR1E, RPL7P29, MTHFD2P2, AL138827.1.
- chr7:63,011,463–103,989,658, 883 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr7:131,661,952–159,233,377, 626 genes, copy number 5–6 (broad region; genes not listed).
- chr8:102,826,308–145,066,685, 632 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr10:35,778,302–44,415,153, 130 genes, copy number 5 (broad region; genes not listed).
- chr15:32,613,733–32,745,106, 7 genes, copy number 6: AC123768.1, ARHGAP11A, AC123768.4, SCG5, SCG5-AS1, AC090877.2, GREM1.
- chr15:32,836,983–32,837,326, 1 gene, copy number 6: AC090877.1.
- chr15:33,293,568–34,108,686, 14 genes, copy number 5: AC055874.1, RYR3, Y_RNA, AC010809.3, AC010809.2, AC010809.1, AVEN, CHRM5, AC009268.2, AC009268.3, AC009268.1, EMC7, AC079203.1, PGBD4.
- chr15:35,546,154–36,252,257, 5 genes, copy number 6 (within-gene range 2–6): DPH6-DT, AC068867.1, LINC02853, MIR4510, AC021351.1.
- chr15:45,587,351–45,676,314, 1 gene, copy number 5 (within-gene range 4–5): AC090527.2.
- chr15:45,631,148–45,931,069, 3 genes, copy number 5: SQOR, AC068722.2, AC068722.1.
- chr15:49,326,962–49,620,929, 1 gene, copy number 5 (within-gene range 2–5): FAM227B.
- chr15:49,423,237–52,569,883, 81 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).
- chr15:53,978,201–54,633,414, 1 gene, copy number 7 (within-gene range 2–7): UNC13C.
- chr15:54,320,731–56,465,137, 35 genes, copy number 7: HNRNPA1P74, AC025272.1, AC011912.1, RSL24D1, RAB27A, AC018926.2, PIGBOS1, PIGB, CCPG1, AC018926.1, AC018926.3, DNAAF4-CCPG1, MIR628, C15orf65, DNAAF4, AC013355.1, PYGO1, AC012378.2, PRTG, AC012378.1, AC009997.1, NEDD4, CNOT6LP1, RN7SL568P, CD24P2, RFX7, AC084783.1, TEX9, AC068726.1, RNU6-1287P, HMGB1P33, AC084782.1, AC084782.2, MNS1, AC084782.3.

Autosomal genes at a single copy (total copy number 1): 11,115. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
